Somatic mutation profile of tumor specimen ALCH-ADXC-TTP1-A (aliquot ALCH-ADXC-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADXC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.2 years (22,725 days).
Specimen ALCH-ADXC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f01b4b-b246-474f-a0a1-be48b515da59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADXC-NB1-A (Blood Derived Normal), aliquot ALCH-ADXC-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6037fec4-d665-494f-abc4-e653beab404a

The open-access MAF lists 111 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 8, Frame Shift Del 5, Intron 5, Splice Site 2, 3'Flank 2, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 268/998 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM29 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 45/225 reads (20%) | catalogued as rs1438157764; called by muse, mutect2, varscan2
- AKR1B1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV53646458; called by muse, mutect2, varscan2
- ANKRD12 | c.2061G>T p.R687S | Missense Mutation (SNP) | VAF 27/656 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV50855116; called by muse, mutect2
- BOD1L1 | c.5214C>A p.N1738K | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99240701; called by muse, mutect2, varscan2
- CDH18 | c.2303G>T p.G768V | Missense Mutation (SNP) | VAF 137/553 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV56900013; called by muse, mutect2, varscan2
- CDH23 | c.336+1G>A p.X112_splice | Splice Site (SNP) | VAF 28/199 reads (14%) | catalogued as rs764824311, CS021738, COSV54944179; called by muse, mutect2, varscan2
- CTNNA2 | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 67/505 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.348); catalogued as COSV63564179; called by muse, mutect2, varscan2
- DSE | c.893A>T p.Y298F | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV59064325; called by muse, mutect2, varscan2
- ENTPD6 | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781381895; called by muse, mutect2, varscan2
- GNE | c.715G>A p.D239N (on ENST00000396594 / NM_001128227.3; = p.D208N on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/630 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as CM133243; called by muse, mutect2, varscan2
- GNS | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 114/903 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs192807123; called by muse, mutect2, varscan2
- HDAC9 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 82/550 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs779864864, COSV67773457; called by muse, mutect2, varscan2
- HMCN1 | c.12386G>C p.S4129T | Missense Mutation (SNP) | VAF 86/559 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV104376238; called by muse, mutect2, varscan2
- HSF4 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99263640; called by muse, mutect2, varscan2
- LRRN4 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1278663423, COSV66644324; called by muse, mutect2, varscan2
- NECAP1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 77/330 reads (23%) | catalogued as COSV60248699; called by muse, mutect2, varscan2
- OR52A5 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56616225; called by muse, mutect2, varscan2
- OR52M1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64171370; called by muse, mutect2, varscan2
- OR56A4 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.54); catalogued as rs1485368132; called by muse, mutect2, varscan2
- OR5AC2 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs898745677, COSV62279462; called by muse, mutect2, varscan2
- SCN3A | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 70/499 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.468); catalogued as COSV99328186; called by muse, mutect2, varscan2
- SLC45A3 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs140557323; called by muse, varscan2
- SLITRK1 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 168/1126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999859; called by muse, mutect2, varscan2
- SMARCA4 | c.3340G>C p.D1114H | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758731, COSV60785929; called by muse, mutect2, varscan2
- SP8 | c.423_427del p.G142Rfs*47 (on ENST00000361443 / NM_198956.4; = p.G160Rfs*47 on NM_182700.6) | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs1407879437; called by mutect2, varscan2*
- SPHKAP | c.3710C>G p.S1237W | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100763913, COSV60875513; called by muse, mutect2
- SRPK2 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1251324810; called by muse, mutect2, varscan2
- UNC79 | c.3403G>T p.D1135Y (on ENST00000393151 / NM_001346218.2; = p.D958Y on NM_020818.5) | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56405663; called by muse, mutect2, varscan2
- UNC80 | c.7421G>A p.G2474D | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1181060447, COSV55887388; called by muse, mutect2, varscan2
- USH2A | c.8845+2T>C p.X2949_splice | Splice Site (SNP) | VAF 104/724 reads (14%) | catalogued as COSV100244044; called by muse, mutect2, varscan2
- XPNPEP1 | c.1622A>G p.H541R | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759079288; called by muse, mutect2, varscan2
- ADGB | c.2783C>A p.A928D | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ADGRV1 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AGTR1 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 74/572 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AHRR | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARMCX1 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ARNT | c.2305del p.Q769Rfs*13 | Frame Shift Del (DEL) | VAF 14/137 reads (10%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6orf141 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CDC45 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CSMD2 | c.10200T>G p.I3400M | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.396); called by muse, mutect2
- DCDC1 | c.4205G>T p.S1402I (on ENST00000597505 / NM_001367979.1; = p.S509I on NM_020869.3) | Missense Mutation (SNP) | VAF 94/672 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- EDC4 | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FAM83B | c.2804G>T p.S935I | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXB2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECW1 | c.4659del p.L1554Ffs*6 | Frame Shift Del (DEL) | VAF 42/293 reads (14%) | called by mutect2, pindel, varscan2
- HEPH | c.2545C>T p.P849S (on ENST00000343002; = p.P582S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HSPA2 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 13/335 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); called by muse, mutect2
- LAMA1 | c.7648A>G p.I2550V | Missense Mutation (SNP) | VAF 106/802 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRK2 | c.4383A>T p.Q1461H | Missense Mutation (SNP) | VAF 114/884 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MDN1 | c.8073dup p.E2692* | Frame Shift Ins (INS) | VAF 34/288 reads (12%) | called by mutect2, varscan2
- MDN1 | c.5868G>T p.Q1956H | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- MUC16 | c.27896C>A p.T9299N | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- NKX2-1 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- NLRP8 | c.1536A>T p.E512D | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- NR4A1 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR5A2 | c.1208T>A p.I403N (on ENST00000367362 / NM_205860.3; = p.I357N on NM_003822.5) | Missense Mutation (SNP) | VAF 83/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR10G9 | c.586A>T p.M196L | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4A16 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OSBPL10 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PLXNA4 | c.4237A>T p.I1413F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PLXNB2 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R3A | c.3071C>A p.A1024E | Missense Mutation (SNP) | VAF 129/1062 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R3A | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 132/1067 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRKCB | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PRKCG | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PTCH2 | c.3463A>T p.R1155* | Nonsense Mutation (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- RBL2 | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINB3 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- SIGLEC6 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SLC6A4 | c.1012G>C p.G338R | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUPT16H | c.2773del p.L925Wfs*92 | Frame Shift Del (DEL) | VAF 21/162 reads (13%) | called by mutect2, pindel, varscan2
- TMEM38B | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM24 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TRIM44 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 49/829 reads (6%) | called by muse, mutect2
- TRPM6 | c.1655C>A p.S552* | Nonsense Mutation (SNP) | VAF 146/1011 reads (14%) | called by muse, mutect2, varscan2
- VPS13B | c.9964G>T p.E3322* | Nonsense Mutation (SNP) | VAF 86/625 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.177A>T p.E59D | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZFP2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- ZNF385C | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNHIT3 | c.348_358del p.N116Kfs*34 | Frame Shift Del (DEL) | VAF 25/298 reads (8%) | called by mutect2, pindel*
- AGPAT5 | c.444C>T p.N148= | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as rs1237242210, COSV99576497; called by muse, mutect2, varscan2
- FZR1 | c.459C>T p.V153= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs764989482; called by muse, mutect2, varscan2
- HOXD3 | c.771C>T p.G257= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- HYAL1 | c.645C>G p.P215= | Silent (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- IGKV6D-21 | c.114C>A p.V38= | Silent (SNP) | VAF 34/267 reads (13%) | called by mutect2, varscan2
- KCNH7 | c.411C>T p.N137= | Silent (SNP) | VAF 29/617 reads (5%) | catalogued as rs759883471, COSV59801263; called by muse, mutect2
- KDM2B | c.3489G>T p.A1163= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- LY6H | c.384G>A p.L128= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- MAU2 | c.951C>A p.L317= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2, varscan2
- MDH1 | c.153C>T p.D51= | Silent (SNP) | VAF 129/1048 reads (12%) | catalogued as rs746932100, COSV51864995; called by muse, mutect2, varscan2
- NPAS1 | c.1179C>T p.P393= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs550532474, COSV53409930, COSV99451479; called by muse, mutect2, varscan2
- PCDHB10 | c.1287C>A p.P429= | Silent (SNP) | VAF 96/625 reads (15%) | catalogued as rs782205520; called by muse, mutect2, varscan2
- PDZRN4 | c.2256A>T p.V752= (on ENST00000402685 / NM_001164595.2; = p.V494= on NM_013377.4) | Silent (SNP) | VAF 34/258 reads (13%) | called by muse, mutect2, varscan2
- SLC9A7 | c.1533G>T p.T511= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV60379274; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.535C>A p.R179= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59565168; called by muse, mutect2, varscan2
- TNFRSF18 | c.96C>T p.P32= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1267457653; called by muse, mutect2, varscan2
- TTN | c.67275T>C p.D22425= (on ENST00000591111; = p.D15001= on NM_003319.4) | Silent (SNP) | VAF 43/258 reads (17%) | catalogued as rs752014113; called by muse, mutect2, varscan2
- ZC3H14 | c.1101A>G p.T367= | Silent (SNP) | VAF 94/553 reads (17%) | catalogued as rs564643161; called by muse, mutect2, varscan2
- ZNF451 | c.2649A>T p.R883= | Silent (SNP) | VAF 52/295 reads (18%) | called by muse, varscan2
- ZNF804A | c.3114A>G p.L1038= | Silent (SNP) | VAF 54/344 reads (16%) | called by muse, mutect2, varscan2
- GRAMD1B | c.374+4309A>G | Intron (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- LINC02410 | n.155C>T | RNA (SNP) | VAF 15/327 reads (5%) | called by muse, mutect2
- NLGN4Y | c.625+10266del | Intron (DEL) | VAF 40/124 reads (32%) | catalogued as rs776557550, COSV52970300; called by mutect2, varscan2
- NOVA1 | c.280+45632C>A | Intron (SNP) | VAF 33/288 reads (11%) | called by muse, mutect2, varscan2
- OR5K2 | chr3:98501483 G>C | 3'Flank (SNP) | VAF 41/291 reads (14%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112220228 T>G | 3'Flank (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
- RN7SL495P | chr15:22611749 C>T | 5'Flank (SNP) | VAF 34/674 reads (5%) | catalogued as rs769594732; called by muse, mutect2
- SPG7 | c.1429-30_1429-23del | Intron (DEL) | VAF 25/187 reads (13%) | called by mutect2, pindel, varscan2
- UMODL1 | c.1900-155A>T | Intron (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
